Gene-level copy-number profile of tumor specimen TCGA-2J-AABP-01A from TCGA case TCGA-2J-AABP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 58.8 years (21,484 days).
Specimen TCGA-2J-AABP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.40eecbe3-8439-45f2-9d6f-bf2df08b3e7c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AABP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a5faa09-6fb8-466c-949e-03acb3a9663f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 1,362; copy number 2: 14,232; copy number 3: 17,119; copy number 4: 11,228; copy number 5: 7,652; copy number 6: 3,928; copy number 7: 2,667; copy number 8: 288; copy number 9: 206; copy number 10: 527; copy number 11: 34; copy number 12: 253; copy number 13: 109; copy number 15: 3; copy number 16: 119; copy number 17: 12; copy number 18: 2; copy number 19: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2J-AABP-01A-11D-A40V-01): tumor purity 0.55, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,331,664, 41 genes: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1.
- chr12:98,931,682–99,105,011, 3 genes: AC069437.1, RNA5SP366, AC117377.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,249 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:137,518,134–139,389,736, 41 genes, copy number 7 (within-gene range 3–7): RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2.
- chr4:13,333,414–60,038,586, 563 genes, copy number 7–12 (broad region; genes not listed).
- chr5:1,544,107–45,895,970, 653 genes, copy number 7–16 (broad region; genes not listed).
- chr5:92,823,935–96,631,085, 58 genes, copy number 7 (within-gene range 5–7): AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1, KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1, MCTP1, AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1, FAM81B, RTRAFP2, TTC37, RNU6-308P, ARSK, GPR150, RFESD, SPATA9, AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2, AC104123.1, AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1, AC099509.2, PCSK1.
- chr7:70,972–23,014,130, 359 genes, copy number 7–18 (broad region; genes not listed).
- chr7:24,196,662–25,949,986, 29 genes, copy number 16: AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A.
- chr7:63,209,219–65,306,238, 121 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:136,092,913–136,437,785, 1 gene, copy number 15 (within-gene range 6–15): AC078845.1.
- chr7:136,262,558–159,233,377, 561 genes, copy number 7–15 (broad region; genes not listed).
- chr11:12,377,563–12,540,967, 2 genes, copy number 16: PARVA, AC009806.1.
- chr11:13,907,484–14,364,506, 6 genes, copy number 16: RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2.
- chr11:37,702,125–40,084,517, 13 genes, copy number 7: AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1.
- chr11:48,907,103–49,059,112, 9 genes, copy number 11: AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, AC084851.4, TRIM64C.
- chr11:101,451,564–101,872,562, 1 gene, copy number 10 (within-gene range 3–10): TRPC6.
- chr11:101,584,295–104,164,379, 55 genes, copy number 7–19 (within-gene range 3–19): AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1.
- chr11:109,002,465–109,583,907, 7 genes, copy number 7: AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1.
- chr12:38,646,822–39,619,803, 12 genes, copy number 7 (within-gene range 5–7): CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3.
- chr17:142,789–2,303,785, 81 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:29,606,283–33,557,470, 83 genes, copy number 8 (broad region; genes not listed).
- chr20:87,250–857,463, 25 genes, copy number 7 (within-gene range 5–7): DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5.
- chr20:15,280,764–17,484,578, 24 genes, copy number 8: RNA5SP475, AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1.
- chr20:17,516,843–17,517,307, 1 gene, copy number 8: RPS27AP2.
- chr20:18,507,520–20,370,949, 32 genes, copy number 8 (within-gene range 6–8): SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1.
- chr20:22,220,554–64,313,132, 1,035 genes, copy number 7 (broad region; genes not listed).
- chr22:19,520,572–28,848,559, 477 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
